Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3819, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3819-01A (Primary Tumor).

Diagnosis

This concerns a moderately differentiated colic adenocarcinoma, G2, with infiltration of all wall layers (pT3), with vascular infiltration L1, V1, with free lymph nodes (pN0) (0/14) as well as free resection margins, corresponding to R0.

Tumor classification

ICDO-DA M-8140/3

G2

pT3, L1, V1, pN0, consistent with R0

Note:

The lymph nodes were relatively large enough to have been worthy of note in CTs or other procedures involving images.

Source: NCI Genomic Data Commons file 1714a118-bdf0-4368-8ca0-465c02effe75 (TCGA-AA-3819.549D5D13-B8AA-4798-9FEA-135BD09D005A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).